PECGS case C083-000035 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum.
https://portal.gdc.cancer.gov/cases/81ea80ad-bbd6-49ee-ab6d-717c15a35a71

Demographics
Sex at birth: female; Age at index: 37 years; Year of birth: 1982; Education level: Vocational College or Some College.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Rectum, NOS; Age at diagnosis: 36.7 years (13,405 days); AJCC clinical stage: Stage IIIB; AJCC pathologic stage: Stage IIA; Progression or recurrence: no.

Other clinical attributes
- BMI: 40.33.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0; Alcohol history: Yes.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample C083-000035_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000035_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
